Gene-level copy-number profile of tumor specimen ALCH-B1LP-TTP1-A from ALCHEMIST case ALCH-B1LP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,629 days).
Specimen ALCH-B1LP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff70b3b9-c838-4439-bfdb-1e6f2cd47b9b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1LP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/db1ab605-a967-4be5-a2b1-989728fecdcb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 6,142; copy number 2: 48,633; copy number 3: 1,609; copy number 4: 1,938; copy number 5: 7; copy number 6: 12; copy number 7: 12; copy number 9: 2; copy number 11: 1; copy number 15: 6; copy number 58: 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,922,554–12,928,253, 2 genes (within-gene range 0–1): RNU6-1072P, PRAMEF29P.
- chr1:13,172,455–13,179,464, 1 gene: PRAMEF9.
- chr1:13,416,351–13,421,328, 1 gene: PRAMEF20.
- chr2:72,932,974–72,934,355, 1 gene (within-gene range 0–2): AC012366.1.
- chr2:90,309,230–90,367,699, 4 genes: AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr2:91,674,857–91,685,884, 2 genes: RNA5SP100, DRD5P1.
- chr7:152,590,641–152,609,434, 4 genes: AC104843.2, 5S_rRNA, AC104843.1, AC003109.1.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–1): AP001271.2.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–1): SHANK2-AS2.
- chr15:23,363,272–23,435,212, 2 genes: RN7SL536P, HERC2P6.
- chr20:47,677,901–47,686,297, 1 gene (within-gene range 0–2): AL354813.1.
- chr22:18,501,794–18,530,573, 5 genes: FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,604,269–234,634,780, 3 genes, copy number 5–7: IRF2BP2, AL160408.2, LINC00184.
- chr7:17,205,652–17,205,928, 1 gene, copy number 5: Metazoa_SRP.
- chr7:30,362,400–30,550,761, 7 genes, copy number 5–6 (within-gene range 4–6): AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5.
- chr7:30,523,143–30,533,613, 2 genes, copy number 6 (within-gene range 4–6): AC005154.2, AC005154.4.
- chr14:104,800,596–104,804,712, 1 gene, copy number 6: ZBTB42.
- chr14:104,857,792–104,896,770, 2 genes, copy number 7–11: AL583810.1, CEP170B.
- chr14:105,093,609–105,100,131, 2 genes, copy number 6: LINC02298, AL512356.4.
- chr14:105,526,583–105,530,202, 1 gene, copy number 7: TMEM121.
- chr16:1,959,538–1,982,929, 10 genes, copy number 6–7 (within-gene range 1–7): NDUFB10, RPS2, SNORA10, SNORA64, AC005363.1, SNHG9, SNORA78, RNF151, AC005363.2, TBL3.
- chr16:1,997,654–2,009,821, 1 gene, copy number 6 (within-gene range 2–6): ZNF598.
- chr17:81,388,126–81,390,319, 1 gene, copy number 6: AC110285.2.
- chr22:18,361,820–18,391,105, 2 genes, copy number 9: FAM230J, AC011718.1.
- chr22:18,533,646–18,653,617, 8 genes, copy number 15–58: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 6,106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
